Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4CE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4CE-01A (Primary Tumor).

[page 1 of 6]
Department of Pathology

Patient Name: [REDACTED]	Copath #: [REDACTED]
MRN: [REDACTED]	Service: Otolaryngology
DOB: [REDACTED]	Visit #: [REDACTED]
Gender: [REDACTED]	Location: [REDACTED]
HCN: [REDACTED]	Facility: [REDACTED]
Ordering MD: [REDACTED]	Collected: [REDACTED]
	Resulted: [REDACTED]

100-0-3

Surgical Pathology Consultation Report

carcinoma, squamous cell, keratin Nif,
Nos 8071/3
Site: Tongue, Nos C 02.9

SPECIMEN(S) RECEIVED

1. Oral-Cavity: Posterior Margin of Tongue
2. Oral Cavity :Right lateral tongue floor of mouth
3. Oral Cavity ;left lateral tongue floor of mouth
4. Oral Cavity :Deep posterior tongue margin
5. Oral Cavity :Dorsum of Tongue Right floor of mouth 1single stitch
anterior 2 double long posterior 1 single short lateral
6. Neck :Right neck contents
7. Neck ;left neck contents
8. Soft Tissue :Right external jugular tissue

hw 7/26/12

DIAGNOSIS

1. Posterior margin of tongue.
Squamous mucosa with chronic inflammation and reactive changes.
Negative for high-grade dysplasia or carcinoma.
2. Right lateral tongue floor of mouth.
Squamous mucosa negative for tumor.
3. Left lateral tongue floor of mouth.
Squamous mucosa negative for tumor.
4. Deep posterior tongue margin.
Skeletal muscle negative for tumor.
5. Oral cavity; dorsum of tongue and right floor of mouth.
Keratinizing squamous cell carcinoma, moderately differentiated. (Please see comment)
- a. Maximum tumor diameter 3.4 cm.
- b. Tumor thickness 1.6 cm.
- c. Positive for perineural invasion.
- d. Negative for lymphovascular invasion.
- e. The posterior and deep margins are positive for tumor. The remaining margins are negative.

[page 2 of 6]
Status: complete

Patient Name	[REDACTED]	Copath #	[REDACTED]
MRN:	[REDACTED]	Service: Otolaryngology	Collected: [REDACTED]
DOB:	[REDACTED]	Visit #:	[REDACTED]
Gender:	[REDACTED]	Location:	Resulted: [REDACTED]
HCN:	[REDACTED]	Facility:	
Ordering MD:	[REDACTED]		

6. Right neck contents.

Twenty-seven lymph nodes negative for tumor (0/27).
Submandibular gland with no pathologic changes.

7. Left neck contents.

Ten lymph nodes negative for tumor (0/10).
Submandibular gland with no pathologic changes.

8. Right external jugular tissue.

Soft tissues with no pathologic changes.
Negative for tumor.

COMMENT

Two of the specimen margins (specimen 5) are positive for tumor; however, the separately submitted patient's margins were negative (see specimens 1-4).

SYNOPTIC DATA

Clinical History:

Specimen:
Received:
Procedure:
floor of mouth

and left neck
Specimen Integrity:
Specimen Size:

Specimen Laterality:
Tumor Site:
Tumor Focality:
Tumor Size:

No neoadjuvant therapy
Dorsal surface of tongue, NOS
Fresh
Glossectomy: dorsum of tongue right

Neck (lymph node) dissection: right

Intact
Greatest dimension: 4.2 cm
Additional dimension: 3 cm
Additional dimension: 1.8 cm
Right
Dorsal surface of tongue, NOS
Single focus
Greatest dimension: 3.4 cm

[page 3 of 6]
Tumor Thickness (pT1 and pT2 tumors):

Tumor Description:
Histologic Type:

Tumor thickness: 16 mm
Exophytic, Endophytic
Squamous cell carcinoma, conventional

Histologic Grade:
Margins:

G2: Moderately differentiated
Margins uninvolved by invasive

Status: complete

Page: 2 of 5

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

carcinoma

Distance from closest margin: 0.1 cm

Margin(s): SEE COMMENT

Margin status for carcinoma in situ

is not applicable

Treatment Effect:

Not identified

Lymph-Vascular Invasion:

Not identified

Perineural Invasion:

Present

Lymph Nodes, Extranodal Extension:

Not identified

TNM Descriptors:

Not applicable

Primary Tumor (pT):

pT2: Tumor more than 2 cm but not

more than 4 cm in greatest dimension

Regional Lymph Nodes (pN):

pN0: No regional lymph node

metastasis

examined: 37

Number of regional lymph nodes

involved: 0

Number of regional lymph nodes

Distant Metastasis (pM):

Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

ELECTRONICALLY VERIFIED BY:

[page 4 of 6]
CLINICAL HISTORY
Tongue CA

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "posterior margin of tongue". It consists of a fragment of tissue measuring 1.7 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

1A frozen section control

2. The specimen is labeled with the patient's name and as "right lateral tongue floor of mouth". It consists of a fragment of tissue measuring 1

Status: complete

Page: 3 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

x 0.5 x 0.2 cm. The specimen is submitted in toto for frozen section.
2A frozen section control

3. The specimen is labeled with the patient's name and as "left lateral tongue floor of mouth". It consists of a fragment of tissue measuring 0.6 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

3A frozen section control

4. The specimen is labeled with the patient's name and as "deep posterior tongue margin". It consists of 2 fragments of tissue measuring 1 x 0.6 x 0.3 and 0.4 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled the patient's name and as "dorsum of tongue right floor of mouth 1 single stitch anterior 2 double long posterior 1 single short lateral". It consists of an oriented portion of tongue measuring 1.8 SI x 3 ML x 4.2 AP cm. There is a raised tumor involving the dorsal surface of the tongue. The tumor measures 1.6 SI x 2.8 ML x 3.4 AP cm. The tumor is homogeneous and partly friable. It is located at 0.3 cm from the lateral margin (double short suture), 0.7 cm from the

[page 5 of 6]
medial margin (opposite to double short), less than 0.1 cm from the deep margin, 0.2 cm from the anterior margin, and close to the posterior margin. Representative sections are submitted.

- 5A anterior margin
- 5B posterior margin
- 5C double short suture margin
- 5D opposite margin of double short
- 5E tumor and deep margin
- 5F tumor

6. The specimen labeled with the patient's name and as "right neck contents". It consists of an oriented left neck dissection with overall dimensions of 18 x 3 x 1 cm. There is a diagram indicating levels I-IV. The submandibular gland measures 2.5 x 3 x 1 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 to 1.2 cm are identified in multiple levels. Representative sections are submitted.

- 6A submandibular gland
- 6B level I, multiple lymph nodes
- 6C level II, one lymph node

Status: complete

Page: 4 of 5

Patient Name: [REDACTED]		Copath #: [REDACTED]
MRN: [REDACTED]	Service: Otolaryngology	Collected: [REDACTED]
DOB: [REDACTED]	Visit #: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Location:	
HCN: [REDACTED]	Facility:	
Ordering MD: [REDACTED]		

-
- 6D-6E level III, multiple lymph nodes
- 6F level IV, multiple lymph nodes
- 6G level IV, four lymph nodes
- 6H level IV, multiple lymph nodes

7. The specimen is labeled with the patient's name and as "left neck contents". It consists of an oriented left neck dissection with overall dimensions of 11 x 6 x 1.2 cm. There is a diagram indicating levels I-IV. The submandibular gland measures 2.5 x 3 x 1 cm and is unremarkable. Multiple lymph nodes ranging from 0.3 to 1.3 cm are identified in multiple levels. Representative sections are submitted.

- 7A submandibular gland
- 7B level I, multiple lymph nodes
- 7C level II, one lymph node bisected
- 7D level III, 2 lymph nodes
- 7E level IV multiple lymph nodes

[page 6 of 6]
8. The specimen is labeled with the patient's name and as "right external jugular tissue". It consists of one piece of soft tissue measuring 1.8 x 1.5 x 0.2 cm. The specimen is submitted in toto.

8A vessel

8B remaining tissue

QUICK SECTION

1-4. Margins (posterior tongue, right lateral tongue/floor of mouth, left lateral tongue/floor of mouth and deep posterior tongue).

- Negative for malignancy.

Called at

Status: complete

Page: 5 of 5

8/28/12

Source: NCI Genomic Data Commons file 053f63b4-d7ca-464c-9ced-f17be839866a (TCGA-CQ-A4CE.5A6C199B-43D6-4E70-862B-1D3E81736B62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).